Somatic mutation profile of tumor specimen TCGA-G9-6356-01A (aliquot TCGA-G9-6356-01A-11D-1786-08) from TCGA case TCGA-G9-6356, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.3 years (22,010 days).
Specimen TCGA-G9-6356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 667f903e-0f72-488f-90f4-973372d88a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6356-10A (Blood Derived Normal), aliquot TCGA-G9-6356-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f40f3e0-23ed-4774-a7f6-3745357fa372

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 3, 3'Flank 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC5 | c.2079C>A p.N693K | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.053); catalogued as COSV55845667; called by muse, mutect2
- DNAH17 | c.8947G>A p.V2983I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV67761910; called by muse, mutect2, varscan2
- GART | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | catalogued as COSV100738174, COSV63114766; called by muse, mutect2
- LHX3 | c.385G>T p.D129Y (on ENST00000371748 / NM_178138.6; = p.D134Y on NM_014564.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65583643; called by muse, varscan2
- LILRA4 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs764565500, COSV52494248, COSV52495251; called by muse, mutect2
- LPIN1 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1230985282, COSV56770230; called by muse, mutect2
- LRIG3 | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100292674, COSV57870737; called by muse, mutect2
- PFKM | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56660643; called by muse, mutect2, varscan2
- PLEKHA5 | c.2735A>G p.H912R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV54713460; called by mutect2, varscan2
- RXFP1 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372722673, COSV57057477; called by muse, mutect2
- SNRNP27 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV54910973; called by muse, mutect2
- TTC30A | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV53710582; called by mutect2, varscan2
- ZFC3H1 | c.1627+2T>G p.X543_splice | Splice Site (SNP) | VAF 7/81 reads (9%) | catalogued as COSV66436270; called by muse, mutect2
- ZNF678 | c.124C>T p.Q42* (on ENST00000343776 / NM_001367910.1; = p.Q97* on NM_178549.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV59389064; called by muse, mutect2
- GSE1 | c.3225dup p.P1076Sfs*34 | Frame Shift Ins (INS) | VAF 13/128 reads (10%) | called by mutect2, pindel, varscan2
- MSH3 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2
- TNS2 | c.2381_2402del p.A794Dfs*44 (on ENST00000314250 / NM_170754.4; = p.A804Dfs*44 on NM_015319.2) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CEP85L | c.2046A>C p.T682= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV63823261, COSV63829138; called by muse, mutect2
- PEG10 | c.378C>T p.T126= (on ENST00000482108 / NM_001040152.2; = p.T160= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV71788636; called by muse, mutect2
- PLA2G4F | c.207G>A p.V69= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV51829765; called by muse, mutect2, varscan2
- HLA-F | chr6:29726943 G>A | 3'Flank (SNP) | VAF 12/163 reads (7%) | catalogued as COSV52577531; called by muse, mutect2
